Surgical pathology report (de-identified scan), TCGA case TCGA-AF-2691, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-2691-01A (Primary Tumor).

[page 1 of 2]
TCGA-AF-2691

SPECIMEN

- A. Ovary and fallopian tube, left, excision
- B. Rectum and sigmoid colon
- C. Additional distal margin of sigmoid colon
- D. Appendix

CLINICAL NOTES

CLINICAL HISTORY: Rectal cancer.

FROZEN SECTION DIAGNOSIS

- A. Left ovary and fallopian tube, excision: Hemorrhagic corpus luteum cyst.
- B. Rectum and sigmoid: Distal margin negative.

GROSS DESCRIPTION

A. The specimen is received fresh for frozen section labeled "A. Left tube and ovary", and consists of a 28 gm, 6 x 3 x 2 cm. ovary and fallopian tube. The ovary contains a 4 cm. hemorrhagic appearing cyst at one edge. The surface is smooth. It varies from tan to purple. The attached fimbriated fallopian tube measures 5 cm. x 1 cm. x 1 cm. and is unremarkable. The specimen is sectioned and the cystic space contains approximately 5 cc of hemorrhagic fluid. The cyst wall is lined by organized blood and otherwise has a smooth lining with some orange areas most suggestive of a hemorrhagic corpus luteum cyst. No solid areas are identified. No papillations are identified. A representative portion of the cyst wall and the adjacent ovary is submitted for frozen section. Additional sections are submitted for permanent sections with sections of ovary in 1 through 5 and sections of fallopian tube in 6. RS-6.

B. Received fresh subsequently fixed in formalin labeled "rectosigmoid colon" is a rectosigmoid colon measuring 22 cm in length. The specimen is partially covered with pink tan smooth glistening serosa and abundant yellow lobular fat. Retroperitoneal

GROSS DESCRIPTION

reflection is 14 cm from the proximal end which is stapled. The proximal end is inked blue, distal is inked black and the specimen is partially covered with pink tan smooth glistening serosa and opened to show a large exophytic friable mass measuring 5.3 x 4.5 x 2 cm. This comes within 0.1 cm from the distal margin. The distal margin is submitted for frozen section as is a representative section of radial margin. The remainder of the mucosa is pink tan smooth glistening with an average circumference of 4.7 cm. The cut surface of the tumor shows invasion into the muscularis propria

[page 2 of 2]
coming within 1.2 cm of the deep margin. Lymph nodes are grossly identified in the fat. Representative sections are submitted as follows:

BLOCK SUMMARY: 1 - Proximal margin; 2 & 3 - representative sections of tumor to deep margin; 5 - nine possible lymph nodes; 6 - eight possible lymph node; 7 - three possible lymph nodes.

C. Received unfixed, labeled "additional margin of sigmoid colon". It consists of a strip of soft pink mucosal tissue, measuring 1.6 x 0.3 x 0.2 cm. AS-1.

D. Received in formalin, labeled "appendix". It consists of a vermiform appendix measuring 4.4 cm. in length and 0.6 cm. in diameter. The serosal surface is smooth, tan and glistening. It has a pinpoint lumen and the wall appears intact. RS-2.

MICROSCOPIC DESCRIPTION

Micro A, C and D performed.

Micro B. The rectal tumor is an invasive moderately differentiated adenocarcinoma arising from a villous adenoma. The villus adenoma component is close to the distal margin. Please see the template below.

MICROSCOPIC DESCRIPTION

Histologic type: Infiltrating adenocarcinoma.

Histologic grade: Moderately differentiated.

Primary tumor (pT): Tumor extends and fills the submucosa without invading the muscularis propria, pT1.

Proximal margin: Negative for tumor.

Distal margin: Negative for tumor.

Circumferential (radial) margin: Negative.

Distance of tumor from closest margin: Adenomatous proliferation is present to within 0.1 cm. of the distal margin.

Vascular invasion: Negative.

Regional lymph nodes (pN): All 17 lymph nodes negative for metastatic disease, 0/17, pN0.

Non-lymph node pericolic tumor: None.

Distant metastasis (pM): Cannot be assessed.

14x2, 3x2, 5, 1

DIAGNOSIS

- A. Left ovary and fallopian tube, left salpingo-oophorectomy -
Ovary with hemorrhagic corpus luteum cyst.
Attached fallopian tube, no significant pathology.
- B. Rectum and sigmoid colon, segmental resection -
Infiltrating moderately differentiated adenocarcinoma of the rectum, arising from a villous adenoma. All margins and all 17 regional lymph nodes negative for tumor.
- C. Additional distal margin of sigmoid colon, excision -
Anorectal tissue, negative for tumor.
- D. Appendix, appendectomy -
Appendix, no significant pathology.
-

Source: NCI Genomic Data Commons file 0cf182f8-0ac3-40c5-9abc-4b21a5bcbb29 (TCGA-AF-2691.45D589A6-010A-4A2E-98D5-7F4031388AC5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).